Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3598, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3598-01A (Primary Tumor).

Diagnosis:

Resected material from the colon and rectum show tumor-free resection margins with an ulcerated, moderately differentiated adenocarcinoma and infiltration of the perimuscular adipose tissue, without any regional lymph node metastases (G2, pT3, pN0, 0/65, L0, V0, R0).

Source: NCI Genomic Data Commons file e8d8fe2d-cb87-409d-96fc-75060719f60e (TCGA-AG-3598.3DAE7086-B8BD-47A3-9F22-475638FDE65B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).